Somatic mutation profile of tumor specimen C3N-01816-01 (aliquot CPT0168080006) from CPTAC case C3N-01816, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.8 years (19,634 days).
Specimen C3N-01816-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fb1a441-48c4-4e84-8a12-eb306fd897a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01816-71 (Blood Derived Normal), aliquot CPT0168120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba37d306-0fe2-4198-bcf6-0155d071eb9e

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/365 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATP10A | c.1493G>T p.S498I | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV63521282; called by muse, mutect2, varscan2
- CLCN5 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 124/355 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56582833; called by muse, mutect2, varscan2
- COL3A1 | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374527092; ClinVar: likely benign; called by muse, mutect2, varscan2
- MESP1 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV55588472; called by muse, mutect2, varscan2
- NCKAP1L | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218763304, COSV53203993; called by muse, mutect2, varscan2
- OR14J1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101012813; called by muse, mutect2, varscan2
- ADGRG4 | c.4753G>T p.V1585F | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- INSM2 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MCEMP1 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RFTN2 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- UNC50 | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ATP1A3 | c.1587G>A p.K529= (on ENST00000545399 / NM_001256214.2; = p.K516= on NM_152296.5) | Silent (SNP) | VAF 92/207 reads (44%) | catalogued as COSV57488286; called by muse, mutect2, varscan2
- DMGDH | c.1314C>A p.T438= | Silent (SNP) | VAF 23/323 reads (7%) | called by muse, mutect2
- DNAH17 | c.13203G>A p.P4401= | Silent (SNP) | VAF 78/164 reads (48%) | catalogued as rs765424936, COSV53143700; called by muse, mutect2, varscan2
- RADIL | c.2928G>A p.T976= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs373238489; called by muse, mutect2, varscan2
- SGF29 | c.243G>A p.L81= | Silent (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- TRAM1 | c.1038T>C p.S346= | Silent (SNP) | VAF 66/155 reads (43%) | called by muse, mutect2, varscan2
- ZNF626 | c.969G>A p.K323= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV74129271; called by muse, mutect2, varscan2
- KRT17P2 | n.1051G>A | RNA (SNP) | VAF 187/326 reads (57%) | called by muse, mutect2, varscan2
- XIAP | c.*1023A>G | 3'UTR (SNP) | VAF 122/343 reads (36%) | called by muse, mutect2, varscan2
